Somatic mutation profile of tumor specimen TARGET-20-PASFZN-09A (aliquot TARGET-20-PASFZN-09A-01D) from TARGET case TARGET-20-PASFZN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.3 years (6,334 days).
Specimen TARGET-20-PASFZN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aa3da84-6e78-487a-85e2-b7ec07509569.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFZN-14A (Bone Marrow Normal), aliquot TARGET-20-PASFZN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6958428-4c21-4e9e-8020-10eb96b58f53

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 23/317 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2
- WT1 | c.1102_1103dup p.S369Gfs*69 | Frame Shift Ins (INS) | VAF 32/215 reads (15%) | catalogued as rs1564972935, COSV60075684, COSV60080453; called by mutect2, pindel, varscan2
- CACNA1A | c.6854C>T p.P2285L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ETV6 | c.257_258insT p.F87Vfs*2 | Frame Shift Ins (INS) | VAF 46/215 reads (21%) | called by mutect2, pindel, varscan2
- LAMB2 | c.5261-25dup | Intron (INS) | VAF 25/121 reads (21%) | catalogued as rs746603871; called by mutect2, varscan2
